MMRF case MMRF_1137 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/87165f32-1939-4050-ad6e-6e1ffa4f9d14

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 1,092 days (3.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.8 years (24,046 days); ISS stage: I; Days to last known disease status: 1,092 days (3.0 years); Days to last follow up: 1,092 days (3.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 195 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 178 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 223 days; Days to treatment end: 224 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days; Days to treatment end: 501 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 632 days (1.7 years); Days to treatment end: 675 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 675 days (1.8 years); Days to treatment end: 722 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 722 days (2.0 years); Days to treatment end: 764 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 785 days (2.1 years); Days to treatment end: 1,090 days (3.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,092.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 52 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.27 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 3.69 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 9.4 g/dL; Glucose 4.29 mmol/L.
- Day 92: M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.933 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 35.4 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 4.48 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 5.58 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 346 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 7.7 g/dL; Glucose 4.73 mmol/L.
- Day 158 (ECOG 0): M Protein 1 g/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.63 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 254 (ECOG 0): M Protein 1.2 g/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 3.16 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 6.01 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 5.12 mmol/L.
- Day 382 (ECOG 0): M Protein 0.4 g/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.57 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 456 (ECOG 0): M Protein 0.5 g/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.51 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.45 mmol/L.
- Day 556 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.733 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.41 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 618 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.708 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.908 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.36 ×10⁹/L; Absolute Neutrophil 3.13 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 4.57 mmol/L.
- Day 694 (ECOG 0): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 28.4 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 8.3 g/dL; Glucose 4.4 mmol/L.
- Day 803 (ECOG 0): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.7 mg/dL; Immunoglobulin G 57.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 4.96 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.93 mmol/L; Albumin 30 g/L; Total Protein 6.9 g/dL; Glucose 7.26 mmol/L.
- Day 897: M Protein 1.8 g/dL; Immunoglobulin G 22.2 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 1.03 g/L; Hemoglobin 5.33 mmol/L; Leukocytes 1.38 ×10⁹/L; Absolute Neutrophil 0.91 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.
- Day 989: M Protein 3.8 g/dL; Immunoglobulin G 50.2 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 4.03 mmol/L; Leukocytes 6.64 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 26 g/L; Total Protein 8.7 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -5: Weight: 69 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (6 samples)
- Sample MMRF_1137_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1137_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
- Sample MMRF_1137_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 158 days.
- Sample MMRF_1137_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 158 days.
- Sample MMRF_1137_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 382 days (1.0 years).
- Sample MMRF_1137_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 803 days (2.2 years).
